TCGA case TCGA-CH-5753 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/928c48a0-68ee-4e28-ae83-9832e52850ca

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 70 years; Vital status: Alive.

Diagnoses (2)
1. Acinar cell carcinoma (the primary disease): ICD-O-3 morphology code: 8550/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 70.6 years (25,780 days); Year of diagnosis: 2008; Method of diagnosis: Core Biopsy; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N1; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 5; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: R0; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 10; Zone of origin prostate: Overlapping/multiple zones.
2. Malignant lymphoma, non-Hodgkin, NOS: ICD-O-3 morphology code: 9591/3; Tissue or organ of origin: Lymph node, NOS; Classification of tumor: Synchronous primary; AJCC staging edition: 6th.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 31 (initial diagnosis): Disease response: Tumor Free; Days to imaging: 31 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 31 (initial diagnosis): Days to imaging: 31 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: No Evidence of Extraprostatic Extension.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 4.53 ng/mL (day 31).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CH-5753-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-CH-5753-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-CH-5753-01A-01-BS1: Section location: Bottom; Percent tumor cells: 25; Percent tumor nuclei: 30; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 55; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CH-5753-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CH-5753-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: No; Lymph nodes examined: Yes; Biochemical recurrence indicator: No.
- Stage record, Psa: PSA most recent results: 4.53.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 5.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Lymph node(s); Other malignancy histological type: Non-Hodgkin's.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Pt with synchronous Non-Hodgkins lymphoma of a lymph node. No systemic chemo or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 31 days; disease-specific survival: no event (censored), 31 days; progression-free interval: no event (censored), 31 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CH-5753-01A-11D-1574-01): tumor purity 0.83, ploidy 1.93, whole-genome doublings 0.
